Somatic mutation profile of tumor specimen TCGA-E1-5302-01A (aliquot TCGA-E1-5302-01A-01D-1468-08) from TCGA case TCGA-E1-5302, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Brain, NOS; Tumor grade: G3; Age at diagnosis: 41.7 years (15,230 days).
Specimen TCGA-E1-5302-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 401fdfea-6ee9-4d00-8e20-3b07c41c05eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E1-5302-10A (Blood Derived Normal), aliquot TCGA-E1-5302-10A-01D-1468-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8400eb1d-48f9-40ff-aae6-09e797f48a49

The open-access MAF lists 34 somatic variants for this specimen: 25 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 22, Silent 9, Frame Shift Del 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 51/155 reads (33%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCA2 | c.2125G>A p.D709N (on ENST00000614293; = p.D679N on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV55802060; called by muse, mutect2, varscan2
- ADGRF5 | c.2762G>A p.S921N | Missense Mutation (SNP) | VAF 49/264 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.723); catalogued as COSV51936456; called by muse, mutect2, varscan2
- ATRX | c.4511_4512del p.R1504Qfs*5 | Frame Shift Del (DEL) | VAF 152/261 reads (58%) | catalogued as COSV64886963; called by mutect2, pindel, varscan2
- CCDC87 | c.1443G>A p.M481I | Missense Mutation (SNP) | VAF 16/367 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs1056936915, COSV59578731, COSV59579693; called by muse, mutect2
- CDH19 | c.1829G>A p.G610E | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.544); catalogued as COSV50964358; called by muse, mutect2
- CELSR1 | c.3307G>A p.D1103N | Missense Mutation (SNP) | VAF 39/439 reads (9%) | SIFT tolerated (0.82); PolyPhen benign (0.023); catalogued as rs145654024, COSV53093821; called by muse, mutect2
- CEP41 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 50/566 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.441); catalogued as rs782089459, COSV56219713; called by muse, mutect2
- DOHH | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.11); catalogued as rs965500521, COSV51745331; called by muse, mutect2, varscan2
- GABRA5 | c.461G>A p.R154Q | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59481768, COSV59482123; called by muse, varscan2
- GANAB | c.877A>C p.M293L | Missense Mutation (SNP) | VAF 34/676 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.225); catalogued as COSV60466373; called by muse, mutect2
- GRM7 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 39/232 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63151796; called by muse, mutect2, varscan2
- HS3ST4 | c.1169A>T p.K390I | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV58821454; called by muse, mutect2, varscan2
- LCLAT1 | c.1225A>G p.N409D | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV58374890; called by muse, mutect2, varscan2
- MCM9 | c.448T>C p.C150R | Missense Mutation (SNP) | VAF 28/406 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60164589; called by muse, mutect2
- MICALL1 | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV53241707; called by muse, mutect2, varscan2
- MTA2 | c.1874T>G p.M625R | Missense Mutation (SNP) | VAF 22/304 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.599); catalogued as COSV53470756; called by muse, mutect2
- OR1C1 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 56/101 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.55); catalogued as rs373256453, COSV68715606; called by muse, mutect2, varscan2
- PDE1A | c.543T>G p.Y181* | Nonsense Mutation (SNP) | VAF 39/299 reads (13%) | catalogued as COSV59527713; called by muse, mutect2, varscan2
- SAXO1 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as rs1387585372, COSV65868657; called by muse, mutect2
- SPATA31E1 | c.2360G>A p.R787H | Missense Mutation (SNP) | VAF 28/225 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.1); catalogued as rs753930842, COSV57793167; called by muse, mutect2, varscan2
- TDG | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 27/263 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57167316; called by muse, mutect2, varscan2
- TMEM109 | c.181G>C p.V61L | Missense Mutation (SNP) | VAF 19/293 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV50011450; called by muse, mutect2
- TP53 | c.837del p.R280Efs*65 | Frame Shift Del (DEL) | VAF 78/124 reads (63%) | catalogued as CD963012, COSV53098982, COSV53696473; called by mutect2, pindel, varscan2
- ZW10 | c.796A>G p.I266V | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs751887837, COSV52317617; called by muse, mutect2
- C3 | c.2655C>T p.T885= | Silent (SNP) | VAF 10/146 reads (7%) | catalogued as rs140780068, COSV55575812; called by muse, mutect2
- CAPN13 | c.1287G>A p.S429= | Silent (SNP) | VAF 104/240 reads (43%) | catalogued as rs752920214, COSV54432498; called by muse, mutect2, varscan2
- HCN3 | c.1827G>A p.A609= | Silent (SNP) | VAF 10/138 reads (7%) | catalogued as COSV61361393; called by muse, mutect2
- MIB2 | c.2004C>T p.R668= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs751140238, COSV61542941; called by muse, mutect2, varscan2
- NDOR1 | c.1659A>G p.A553= (on ENST00000371521 / NM_001144026.3; = p.A537= on NM_014434.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 19/163 reads (12%) | catalogued as COSV61288781; called by muse, mutect2, varscan2
- PLD3 | c.1290C>G p.T430= | Silent (SNP) | VAF 23/171 reads (13%) | catalogued as rs199717679, COSV52522528; called by muse, mutect2, varscan2
- RNF133 | c.768C>T p.C256= | Silent (SNP) | VAF 135/517 reads (26%) | catalogued as rs765263043, COSV57371811; called by muse, mutect2, varscan2
- SCRN1 | c.1113C>T p.T371= | Silent (SNP) | VAF 19/180 reads (11%) | catalogued as COSV54131972; called by muse, mutect2
- STAB2 | c.1659C>T p.Y553= | Silent (SNP) | VAF 63/119 reads (53%) | catalogued as rs753537088, COSV66341960; called by muse, mutect2, varscan2
